Somatic mutation profile of tumor specimen TCGA-UC-A7PD-01A (aliquot TCGA-UC-A7PD-01A-11D-A351-09) from TCGA case TCGA-UC-A7PD, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB; Tumor grade: G2; Age at diagnosis: 21.5 years (7,855 days).
Specimen TCGA-UC-A7PD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5d225c73-9440-4351-b0ee-d5d4a127918f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-UC-A7PD-11A (Solid Tissue Normal), aliquot TCGA-UC-A7PD-11A-12D-A351-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cbde8770-80fd-48aa-8a68-104f4fdebe6f

The open-access MAF lists 35 somatic variants for this specimen: 27 protein-altering or splice-affecting, 7 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 7, Nonsense Mutation 4, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARIH2 | c.1295A>T p.Y432F | Missense Mutation (SNP) | VAF 11/131 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.788); catalogued as COSV100711306; called by muse, mutect2
- ELAPOR1 | c.337G>C p.E113Q | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.206); catalogued as COSV100884606; called by muse, varscan2
- FOXG1 | c.13G>T p.G5* | Nonsense Mutation (SNP) | VAF 4/70 reads (6%) | catalogued as COSV100486533; called by muse, mutect2
- GCA | c.472C>G p.Q158E | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.141); catalogued as COSV99280553; called by muse, mutect2
- HRC | c.1779G>T p.R593S | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV53258788; called by muse, mutect2, varscan2
- HRC | c.1345G>C p.E449Q | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0.067); catalogued as rs1245588072, COSV53258779; called by muse, mutect2, varscan2
- IBA57 | c.908C>T p.S303L | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.055); catalogued as COSV64511247; called by muse, mutect2, varscan2
- INTS11 | c.163G>A p.G55S | Missense Mutation (SNP) | VAF 43/112 reads (38%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.727); catalogued as rs779574336; called by muse, mutect2, varscan2
- LY96 | c.353C>T p.S118L | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.042); catalogued as rs868086563, COSV99514528; called by muse, mutect2, varscan2
- MYOT | c.1327C>T p.R443C | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as rs192257955, COSV99296267; called by muse, mutect2, varscan2
- PGR | c.2049G>C p.L683F | Missense Mutation (SNP) | VAF 19/610 reads (3%) | SIFT tolerated (0.57); PolyPhen benign (0.02); catalogued as COSV99678283; called by muse, mutect2
- PPP1R21 | c.1696C>T p.Q566* | Nonsense Mutation (SNP) | VAF 10/60 reads (17%) | catalogued as COSV99682752; called by muse, mutect2, varscan2
- SPEN | c.9928G>A p.D3310N | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.981); catalogued as rs747459170; called by muse, mutect2, varscan2
- ZDHHC23 | c.1087G>T p.A363S | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.031); catalogued as COSV100362140; called by muse, mutect2
- ANKRD20A1 | c.1972G>C p.E658Q | Missense Mutation (SNP) | VAF 14/142 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.234); called by mutect2, varscan2
- ARMC3 | c.1792C>G p.L598V | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- BPTF | c.2290C>G p.P764A | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- CACNA1B | c.2032G>A p.G678S | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DOLK | c.1181T>A p.L394H | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- HNRNPR | c.1102G>A p.E368K | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- LTN1 | c.444G>A p.M148I | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- PANX3 | c.562G>A p.E188K | Missense Mutation (SNP) | VAF 24/42 reads (57%) | SIFT tolerated (0.93); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PIM2 | c.574G>C p.E192Q | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- PNLIPRP2 | c.1387C>T p.Q463* (on ENST00000611850; = p.Q464* on NM_005396.5) | Nonsense Mutation (SNP) | VAF 25/61 reads (41%) | called by muse, mutect2, varscan2
- PTPRD | c.2560C>T p.Q854* | Nonsense Mutation (SNP) | VAF 20/88 reads (23%) | called by muse, mutect2, varscan2
- SEC14L1 | c.135C>G p.F45L | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (0.63); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- UGT1A6 | c.409A>T p.N137Y | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- CNOT1 | c.195C>G p.G65= | Silent (SNP) | VAF 33/69 reads (48%) | called by muse, mutect2, varscan2
- IL12RB2 | c.2277G>A p.E759= | Silent (SNP) | VAF 12/53 reads (23%) | called by muse, mutect2, varscan2
- NTNG2 | c.1026C>T p.N342= | Silent (SNP) | VAF 33/104 reads (32%) | catalogued as rs201475380; called by muse, mutect2, varscan2
- PRDM9 | c.1653C>G p.L551= | Silent (SNP) | VAF 39/147 reads (27%) | catalogued as COSV99690352; called by muse, mutect2, varscan2
- SPEN | c.9585G>C p.V3195= | Silent (SNP) | VAF 13/56 reads (23%) | catalogued as COSV65357625; called by muse, mutect2, varscan2
- TUFM | c.570G>A p.Q190= | Silent (SNP) | VAF 3/47 reads (6%) | catalogued as COSV100492592; called by muse, mutect2
- USP43 | c.333C>T p.F111= | Silent (SNP) | VAF 39/96 reads (41%) | called by muse, mutect2, varscan2
- KATNIP | c.540+5990C>G | Intron (SNP) | VAF 37/138 reads (27%) | catalogued as COSV99851012; called by muse, mutect2, varscan2
